TARGET case TARGET-30-PARCWT — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Heart, mediastinum, and pleura. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/adb89d64-261e-585a-a383-5068c95ca4d3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Dead; Days to death: 2,522 days (6.9 years).

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C38.3; Tissue or organ of origin: Mediastinum, NOS; Classification of tumor: primary; Age at diagnosis: 2.8 years (1,026 days); Year of diagnosis: 2007; Days to last follow up: 2,522 days (6.9 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Differentiating; INSS stage: Stage 4.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 20.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ADVL0921.
   Treatment given: Protocol identifier: ANBL1021.

Follow-up (2 entries)
- Days to follow up: 968 days (2.7 years); Days to first event: 968 days (2.7 years); First event: Event.
- Days to follow up: 2,522 days (6.9 years); Year of follow up: 2013.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PARCWT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PARCWT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 2522
- Protocol: ANBL00B1, ADVL0921, ANBL1021
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- Diagnostic Category: Ganglioneuroblastoma, nodular
- Percent Tumor v/s Stroma: 20/80
